Somatic mutation profile of tumor specimen BA2829D (aliquot aq-BA2829D) from BEATAML1.0 case 2238, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,694 days).
Specimen BA2829D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98ecb2a4-bbf3-4b36-bd52-cbd7ec5e812c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2895D (Solid Tissue Normal), aliquot aq-BA2895D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/170f4c48-1efe-4c99-95ae-77bf1fc2b099

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Intron 3, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2644C>T p.R882C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs377577594, COSV53036332, COSV53037241, COSV53063308; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ATG2B | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs1485646079; called by muse, mutect2, varscan2
- GABRB3 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 109/346 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54676421; called by muse, mutect2, varscan2
- GJA8 | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV99569218; called by muse, mutect2, varscan2
- MROH1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370172700; called by muse, varscan2
- MUC16 | c.9539C>T p.T3180M | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as rs751672175, COSV67502940; called by muse, mutect2, varscan2
- PCDHGA7 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs371173445; called by muse, mutect2, varscan2
- PLXNA3 | c.4186G>A p.E1396K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs1342632484, COSV63755386; called by muse, mutect2
- SERPINI1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369596299; ClinVar: likely benign; called by muse, mutect2, varscan2
- TBL3 | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs371870760; called by muse, mutect2, varscan2
- TET2 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 45/149 reads (30%) | catalogued as rs1470568364; called by muse, mutect2, varscan2
- BTBD2 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CFAP44 | c.1174T>A p.W392R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- FGD6 | c.518T>C p.V173A | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GAS6 | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- PCDH11X | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 74/183 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SGSM1 | c.1022T>G p.V341G | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MMP9 | c.1200G>A p.A400= | Silent (SNP) | VAF 76/302 reads (25%) | catalogued as rs201927079, COSV63434310; called by muse, mutect2, varscan2
- PKD1L2 | c.2325G>A p.V775= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1424013743; called by muse, mutect2, varscan2
- SLC12A5 | c.1515A>C p.P505= (on ENST00000454036 / NM_001134771.2; = p.P482= on NM_020708.5) | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV54804404; called by muse, mutect2, varscan2
- UGT2B4 | c.1272C>T p.D424= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as rs375919634; called by muse, mutect2, varscan2
- ARPC4 | c.-4C>T | 5'UTR (SNP) | VAF 18/68 reads (26%) | catalogued as rs1289261043; called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs73150876; called by muse, mutect2
- MAP1S | c.119-480C>A | Intron (SNP) | VAF 4/63 reads (6%) | called by muse, mutect2
- PNKP | c.1386+45C>T | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
